Gene-level copy-number profile of tumor specimen TCGA-43-3920-01A from TCGA case TCGA-43-3920, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.3 years (26,059 days).
Specimen TCGA-43-3920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.aa7ce4dd-bc30-4196-903a-47d050802ed9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-3920-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/428c933f-74f9-482b-ad98-30c5d22c5951

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 663; copy number 2: 16,497; copy number 3: 19,023; copy number 4: 9,700; copy number 5: 6,127; copy number 6: 5,490; copy number 7: 1,028; copy number 8: 638; copy number 9: 272; copy number 10: 13; copy number 11: 43; copy number 12: 179; copy number 16: 76.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-3920-01A-01D-1549-01): tumor purity 0.52, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,426,546–186,726,722, 4 genes (within-gene range 0–2): AC018709.1, RNU6-1055P, MTNR1A, FAT1.
- chr9:21,966,929–28,670,286, 62 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,249 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,623,184–19,485,539, 155 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:92,508,696–96,022,890, 81 genes, copy number 7–9 (broad region; genes not listed).
- chr1:168,903,905–169,087,005, 1 gene, copy number 7 (within-gene range 5–7): LINC00970.
- chr1:169,059,576–178,677,834, 177 genes, copy number 7 (broad region; genes not listed).
- chr2:52,722,671–52,961,452, 3 genes, copy number 7 (within-gene range 3–7): AC010967.1, AC010967.2, AC010967.3.
- chr2:57,289,648–57,544,599, 3 genes, copy number 9: AC132153.1, AC068276.1, AC073875.1.
- chr4:58,780,626–60,922,684, 16 genes, copy number 7: AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1.
- chr4:72,031,804–76,112,802, 76 genes, copy number 16 (broad region; genes not listed).
- chr5:1,931,064–45,895,970, 636 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:26,667,068–30,179,014, 99 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:31,751,179–32,428,131, 2 genes, copy number 8 (within-gene range 5–8): PDE1C, SNX2P2.
- chr7:35,313,838–35,907,105, 11 genes, copy number 7: AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2.
- chr7:40,135,005–40,860,763, 1 gene, copy number 9 (within-gene range 5–9): SUGCT.
- chr7:40,538,127–40,785,217, 2 genes, copy number 9: SUGCT-AS1, AC005160.1.
- chr7:97,732,084–100,400,096, 111 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:122,994,704–124,033,067, 20 genes, copy number 7–12: TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A.
- chr17:66,197,693–77,099,902, 306 genes, copy number 7–12 (broad region; genes not listed).
- chr17:77,089,307–77,089,497, 2 genes, copy number 12: SCARNA16, MIR6516.
- chr19:3,630,183–3,768,575, 7 genes, copy number 11 (within-gene range 2–11): PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54.
- chr20:87,250–26,251,546, 540 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 663. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
